Gene-level copy-number profile of tumor specimen TCGA-D3-A2JG-06A from TCGA case TCGA-D3-A2JG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 39.2 years (14,330 days).
Specimen TCGA-D3-A2JG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.eae1b435-ad05-470d-aeb1-47e1b1a5720d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2JG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98754edc-5ec9-40a6-84a4-e7ced2680d44

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 10,048; copy number 2: 45,039; copy number 3: 4,436; copy number 4: 138; copy number 7: 11; copy number 9: 53; copy number 15: 31; copy number 16: 11; copy number 25: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2JG-06A-11D-A194-01): tumor purity 0.8, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,038,842–62,078,859, 4 genes: LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 148 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:83,397,555–85,578,363, 42 genes, copy number 25 (within-gene range 2–25): AC116099.1, LINC01712, LINC01725, AL035706.1, TTLL7, TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA.
- chr3:62,398,346–64,103,131, 26 genes, copy number 15 (within-gene range 2–15): CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994.
- chr3:64,099,273–64,200,965, 4 genes, copy number 15: PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3.
- chr3:68,500,613–72,998,138, 65 genes, copy number 9–16 (within-gene range 2–16) (broad region; genes not listed).
- chr7:38,256,337–38,311,808, 9 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:76,818,377–76,919,191, 2 genes, copy number 7: AC006972.1, AC007003.1.

Autosomal genes at a single copy (total copy number 1): 8,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
